Somatic mutation profile of tumor specimen ALCH-ABY0-TTP1-A (aliquot ALCH-ABY0-TTP1-A-1-0-D-A49D-36) from ALCHEMIST case ALCH-ABY0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.2 years (27,476 days).
Specimen ALCH-ABY0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7942ff0a-4f2d-4472-baec-b2c9c80a64da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABY0-NB1-A (Blood Derived Normal), aliquot ALCH-ABY0-NB1-A-1-0-D-A49D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/336318ca-27f6-4130-a527-eef2398e8045

The open-access MAF lists 48 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 10, Intron 3, Frame Shift Del 2, 3'UTR 1, In Frame Del 1, Splice Region 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2240_2254del p.L747_T751del | In Frame Del (DEL) | VAF 252/1331 reads (19%) | hotspot (GDC flag); catalogued as rs121913442, COSV51863059; ClinVar: drug response; called by mutect2, pindel, varscan2
- ALS2 | c.3292G>A p.D1098N | Missense Mutation (SNP) | VAF 60/546 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV51891152; called by muse, varscan2
- CAMKV | c.595C>T p.R199C | Missense Mutation (SNP) | VAF 28/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs774782174, COSV56556107; called by muse, mutect2
- CDC5L | c.1862A>T p.Y621F | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.076); catalogued as rs758049414; called by muse, mutect2
- CLCA2 | c.770C>G p.T257S | Missense Mutation (SNP) | VAF 78/390 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.492); catalogued as rs761719997; called by muse, mutect2, varscan2
- DHRS13 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs370845006; called by muse, mutect2
- GABRA1 | c.434T>G p.L145R | Missense Mutation (SNP) | VAF 35/640 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as COSV50104223, COSV99195703; called by muse, mutect2
- IGHV3-48 | c.173A>G p.Q58R | Missense Mutation (SNP) | VAF 56/962 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.603); catalogued as rs1555530663; called by muse, mutect2
- L3MBTL4 | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 22/138 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs1281211736; called by muse, mutect2, varscan2
- NLRP7 | c.2809C>T p.R937W (on ENST00000340844 / NM_206828.3; = p.R909C on NM_139176.3) | Missense Mutation (SNP) | VAF 27/776 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs145163808; called by muse, mutect2
- POM121L12 | c.422T>A p.I141N | Missense Mutation (SNP) | VAF 44/1176 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101374986, COSV101375002; called by muse, mutect2
- RAPGEF6 | c.2371G>A p.D791N | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.217); catalogued as rs1041364031, COSV99726731; called by muse, mutect2, varscan2
- TP53 | c.466del p.R156Afs*14 | Frame Shift Del (DEL) | VAF 92/435 reads (21%) | catalogued as CD156964, COSV52711846, COSV52730924, COSV53119766; called by mutect2, pindel, varscan2
- ZNF488 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs374041008; called by muse, mutect2, varscan2
- ABCA2 | c.410G>T p.G137V (on ENST00000614293; = p.G107V on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/160 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- AC100868.1 | c.1592G>A p.C531Y | Missense Mutation (SNP) | VAF 45/607 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRG4 | c.8368C>G p.L2790V | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGEF25 | c.535T>A p.L179M | Missense Mutation (SNP) | VAF 48/230 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DDC | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 124/1498 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- GGT5 | c.1121G>C p.S374T | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.196); called by muse, mutect2
- GOPC | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 11/294 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- HSD17B13 | c.325A>G p.K109E | Missense Mutation (SNP) | VAF 26/208 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- INTS6L | c.1901C>G p.P634R | Missense Mutation (SNP) | VAF 65/525 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LHFPL6 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 94/566 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NRK | c.932C>A p.P311Q | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2
- SLC35F1 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMPDL3B | c.401del p.N134Ifs*21 | Frame Shift Del (DEL) | VAF 25/273 reads (9%) | called by mutect2, pindel, varscan2
- ST8SIA3 | c.482T>C p.I161T | Missense Mutation (SNP) | VAF 27/175 reads (15%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- TMC8 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- TRIM53AP | n.415+2T>C | Splice Site (SNP) | VAF 23/192 reads (12%) | called by mutect2, varscan2
- TRIP6 | c.237+5G>T | Splice Region (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- UTP3 | c.1435A>C p.K479Q | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- ZNF107 | c.134G>C p.R45T | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- AMER3 | c.528G>A p.S176= | Silent (SNP) | VAF 49/352 reads (14%) | catalogued as rs776935592, COSV58467357, COSV58469465; called by muse, mutect2, varscan2
- APOBEC3G | c.495G>A p.V165= | Silent (SNP) | VAF 32/504 reads (6%) | catalogued as rs369259268; called by muse, mutect2
- CACNA1E | c.1782C>G p.V594= | Silent (SNP) | VAF 112/378 reads (30%) | called by muse, mutect2, varscan2
- CAPN1 | c.1632C>T p.D544= | Silent (SNP) | VAF 54/637 reads (8%) | catalogued as rs770233534; called by muse, mutect2
- FANCD2 | c.2205G>T p.R735= | Silent (SNP) | VAF 55/993 reads (6%) | called by muse, mutect2
- HSPA9 | c.765G>A p.L255= | Silent (SNP) | VAF 42/370 reads (11%) | called by muse, varscan2
- MUC2 | c.1533A>G p.Q511= | Silent (SNP) | VAF 51/422 reads (12%) | called by muse, mutect2, varscan2
- RIPOR2 | c.3120G>T p.R1040= | Silent (SNP) | VAF 37/187 reads (20%) | called by muse, mutect2, varscan2
- SLC4A9 | c.1584G>A p.E528= (on ENST00000507527 / NM_001258428.2; = p.E504= on NM_031467.3) | Silent (SNP) | VAF 61/1189 reads (5%) | catalogued as rs776197961; called by muse, mutect2
- ZNF792 | c.1557C>T p.S519= | Silent (SNP) | VAF 27/204 reads (13%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502703 A>G | 5'Flank (SNP) | VAF 9/49 reads (18%) | catalogued as rs775812432; called by muse, mutect2, varscan2
- DAP | c.*215G>C | 3'UTR (SNP) | VAF 318/891 reads (36%) | called by muse, varscan2
- GALNT9 | c.1077+7284G>A | Intron (SNP) | VAF 31/806 reads (4%) | called by muse, mutect2
- L3MBTL2 | c.25-1423G>A | Intron (SNP) | VAF 15/166 reads (9%) | called by muse, mutect2
- LGALS9 | c.333+250A>C | Intron (SNP) | VAF 11/131 reads (8%) | called by muse, mutect2
